MMRF case MMRF_1564 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1def61bf-1d48-4579-8c22-96718dce8ccf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 86 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 86.6 years (31,640 days); ISS stage: II; Days to last known disease status: 1,297 days (3.6 years); Days to last follow up: 1,206 days (3.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 72 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 193 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 72 days; Days to treatment end: 137 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 137 days; Days to treatment end: 193 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 193 days; Days to treatment end: 216 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 193 days; Days to treatment end: 1,215 days (3.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 216 days; Days to treatment end: 528 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 528 days (1.4 years); Days to treatment end: 603 days (1.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 603 days (1.7 years); Days to treatment end: 884 days (2.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 884 days (2.4 years); Days to treatment end: 1,215 days (3.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 1): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 27.2 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.493 g/L; Beta 2 Microglobulin 4.3 µg/mL; Lactate Dehydrogenase 1.82 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.5 mmol/L; Albumin 38 g/L; Total Protein 8.3 g/dL; Glucose 5.17 mmol/L; C-Reactive Protein 0.41 mg/dL.
- Day 72 (ECOG 1): M Protein 0.231 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.66 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 2.63 g/L; Immunoglobulin M 0.797 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 10.7 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 6.82 mmol/L.
- Day 193 (ECOG 1): M Protein 0.0536 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.72 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 3.08 g/L; Immunoglobulin M 0.7 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 5.67 mmol/L.
- Day 291 (ECOG 1): M Protein 0.0272 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.76 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 4.59 g/L; Immunoglobulin M 0.94 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 6.37 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 7.32 mmol/L.
- Day 417 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.62 mg/dL; Immunoglobulin G 9.33 g/L; Immunoglobulin A 3.63 g/L; Immunoglobulin M 0.75 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 6.77 mmol/L.
- Day 506 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 3.96 g/L; Immunoglobulin M 0.63 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 4.13 mmol/L.
- Day 603 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.83 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 4.37 g/L; Immunoglobulin M 0.59 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.6 g/dL; Glucose 4.29 mmol/L.
- Day 695 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.41 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 5.22 g/L; Immunoglobulin M 0.63 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 4.95 mmol/L.
- Day 793 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 4.46 g/L; Immunoglobulin M 0.52 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.9 g/dL; Glucose 5.72 mmol/L.
- Day 884 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 4.3 g/L; Immunoglobulin M 0.52 g/L; Hemoglobin 8 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 7.32 mmol/L.
- Day 968 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 4.01 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.9 g/dL; Glucose 5.72 mmol/L.
- Day 1,031 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 3.85 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 10.4 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 6.9 g/dL; Glucose 7.7 mmol/L.
- Day 1,115 (ECOG 1): M Protein 0.0325 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.47 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 3.99 g/L; Immunoglobulin M 0.55 g/L; Hemoglobin 8 mmol/L; Leukocytes 10.4 ×10⁹/L; Absolute Neutrophil 8.12 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 6.5 g/dL; Glucose 6.05 mmol/L.
- Day 1,206 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.1 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 3.81 g/L; Immunoglobulin M 0.55 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 9.4 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 7.04 mmol/L.

Other clinical attributes
- Day -12: Weight: 90 kg; Height: 179 cm.

Family history
- Relative with cancer history: yes; Relationship type: Child.

Biospecimens (2 samples)
- Sample MMRF_1564_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1564_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
